Gene-level copy-number profile of tumor specimen TCGA-UY-A78N-01A from TCGA case TCGA-UY-A78N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.8 years (29,132 days).
Specimen TCGA-UY-A78N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f5895f8e-d8b2-4c5d-bef4-3f547ac5798a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A78N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40eb4439-5298-4872-a57b-91a44672c0f0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 393; copy number 2: 10,420; copy number 3: 23,559; copy number 4: 24,031; copy number 5: 894; copy number 6: 63; copy number 7: 40; copy number 8: 112; copy number 10: 5; copy number 11: 14; copy number 12: 6; copy number 13: 113; copy number 14: 48; copy number 15: 1; copy number 18: 103; copy number 19: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A78N-01A-12D-A338-01): tumor purity 0.78, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:136,553,236–136,553,739, 1 gene: AC093875.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 296 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:20,534,457–21,271,132, 5 genes, copy number 10 (within-gene range 6–10): CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1.
- chr20:31,257,664–33,811,109, 103 genes, copy number 18 (broad region; genes not listed).
- chr20:36,306,336–36,646,196, 9 genes, copy number 11: DLGAP4, DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2.
- chr20:36,668,559–36,668,670, 1 gene, copy number 11: Y_RNA.
- chr20:39,213,777–40,126,357, 10 genes, copy number 11–19: LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1.
- chr20:40,854,119–45,491,671, 112 genes, copy number 13 (broad region; genes not listed).
- chr20:46,499,630–46,736,347, 7 genes, copy number 13–14: ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10.
- chr20:47,904,348–47,990,127, 6 genes, copy number 12: RNU7-92P, AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523.
- chr20:50,247,643–52,670,578, 42 genes, copy number 14 (within-gene range 6–14): PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4.
- chr20:55,775,176–55,781,231, 1 gene, copy number 15: AL109828.1.

Autosomal genes at a single copy (total copy number 1): 393. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
